Somatic mutation profile of tumor specimen TCGA-DD-A4NS-01A (aliquot TCGA-DD-A4NS-01A-11D-A30V-10) from TCGA case TCGA-DD-A4NS, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.0 years (22,638 days).
Specimen TCGA-DD-A4NS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddd9414a-b8e4-48f8-803f-c22a8cbd03bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NS-10A (Blood Derived Normal), aliquot TCGA-DD-A4NS-10A-01D-A30V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6601ffae-5f7f-45cb-95ab-ec81a4fbad7b

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Nonsense Mutation 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AURKA | c.539G>A p.R180K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57167407; called by muse, mutect2
- BAZ2B | c.199A>C p.S67R | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs746086944, COSV58595973; called by muse, mutect2
- C5orf51 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101068997, COSV67565456; called by muse, mutect2
- CACNA2D4 | c.2551G>A p.A851T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV54563702; called by muse, varscan2
- CARD16 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs889939311, COSV65212709; called by muse, mutect2, varscan2
- CD8B | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 36/458 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV58925068; called by muse, mutect2
- CDKN2AIP | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 13/122 reads (11%) | catalogued as COSV100187557, COSV56628204; called by mutect2, varscan2
- DNAH12 | c.1145C>A p.T382K | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV60855584; called by muse, mutect2
- EPHA10 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60402201; called by muse, mutect2, varscan2
- FREM2 | c.2998C>G p.P1000A | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV54828829, COSV99746842; called by muse, mutect2
- GFPT2 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53806467; called by muse, mutect2, varscan2
- GPR137C | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.028); catalogued as COSV58703987; called by muse, mutect2
- GRIA3 | c.1084C>A p.Q362K | Missense Mutation (SNP) | VAF 31/541 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV52049681; called by muse, mutect2
- GUCA2A | c.147G>T p.R49S | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV100813044; called by muse, mutect2
- KIAA1210 | c.586T>C p.S196P | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.456); catalogued as rs1312805334, COSV68175538; called by muse, mutect2
- KLHL9 | c.287A>C p.H96P | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV62921179; called by muse, mutect2
- LHPP | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV64328262; called by muse, mutect2
- NAGLU | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as rs141018386; called by muse, mutect2, varscan2
- NF1 | c.4796C>A p.S1599Y (on ENST00000358273 / NM_001042492.3; = p.S1578Y on NM_000267.3) | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM077303, COSV62193034, COSV62193541, COSV62220082; called by muse, mutect2
- NPTXR | c.920C>A p.A307D | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60727683; called by muse, mutect2, varscan2
- OXTR | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1244817296, COSV57478421, COSV57479410; called by muse, mutect2
- PCDHGB7 | c.1628G>T p.S543I | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV53901467; called by muse, mutect2
- PCNX2 | c.862G>C p.V288L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV50782401; called by mutect2, varscan2
- SBK2 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV60013251; called by muse, mutect2, varscan2
- SCN3A | c.5524G>C p.V1842L | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51801746; called by muse, mutect2
- SLC13A1 | c.931A>T p.N311Y | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52008207; called by muse, mutect2
- SVEP1 | c.5463G>T p.L1821F | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV52835655; called by muse, mutect2
- TKTL2 | c.1030G>T p.G344C | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54917453; called by muse, mutect2
- TTN | c.23126T>C p.V7709A (on ENST00000591111; = p.V6782A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/109 reads (7%) | PolyPhen benign (0.033); catalogued as COSV59895591; called by muse, mutect2
- ZBTB40 | c.2019A>C p.E673D | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV65144654; called by muse, mutect2
- ZC3HAV1 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV54293472; called by muse, mutect2
- ZNF300 | c.1403C>A p.T468N | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV51031986; called by muse, mutect2
- ZNF430 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 18/162 reads (11%) | catalogued as COSV55108079; called by muse, mutect2, varscan2
- CD46 | c.601del p.S201Hfs*32 | Frame Shift Del (DEL) | VAF 19/127 reads (15%) | called by mutect2, pindel, varscan2
- MUC2 | c.1286T>A p.L429Q | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.172); called by muse, mutect2
- TBC1D16 | c.629A>G p.D210G | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- APOL4 | c.717C>T p.A239= (on ENST00000352371 / NM_145660.2; = p.A236= on NM_030643.4) | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as rs1438688978, COSV60653991, COSV60655502; called by muse, mutect2
- CPN1 | c.777C>A p.S259= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV64941936; called by muse, mutect2, varscan2
- CXCR4 | c.987C>T p.L329= | Silent (SNP) | VAF 22/201 reads (11%) | catalogued as rs1284991536, COSV54010300; called by muse, mutect2, varscan2
- GRM4 | c.2310T>C p.Y770= | Silent (SNP) | VAF 10/167 reads (6%) | catalogued as COSV65210757; called by muse, mutect2
- KSR2 | c.963C>T p.R321= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as rs1025244189, COSV60366545; called by muse, mutect2
- MAPK6 | c.606T>G p.L202= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as COSV55928836; called by muse, mutect2
- OR51S1 | c.750C>A p.A250= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as COSV59057304; called by muse, mutect2, varscan2
- PNPLA6 | c.2154G>A p.T718= (on ENST00000414982 / NM_001166111.2; = p.T670= on NM_006702.5) | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV55373898; called by muse, mutect2, varscan2
- PRKACA | c.510G>A p.P170= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs763611702, COSV58066728; called by muse, mutect2
- SESTD1 | c.885A>G p.Q295= | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as COSV58930263; called by muse, mutect2
- SYNGR1 | c.90C>A p.V30= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV53367588; called by muse, mutect2, varscan2
- ZNF517 | c.759C>T p.R253= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1161267155, COSV63464507; called by muse, mutect2
- OR2W5 | n.1246G>T | RNA (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
